Somatic mutation profile of tumor specimen TCGA-W5-AA31-01A (aliquot TCGA-W5-AA31-01A-11D-A417-09) from TCGA case TCGA-W5-AA31, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 71.6 years (26,139 days).
Specimen TCGA-W5-AA31-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03c8e108-6d20-4387-b49a-bb4f6bb25977.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA31-10A (Blood Derived Normal), aliquot TCGA-W5-AA31-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b966566-3e8f-4c95-8013-2b020c41192e

The open-access MAF lists 37 somatic variants for this specimen: 33 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 29, Silent 4, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM30 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1243918038, COSV65560687; called by muse, mutect2, varscan2
- ADAMTS12 | c.1445A>G p.Y482C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140311659; called by muse, mutect2, varscan2
- BAP1 | c.588G>A p.W196* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as CM134973, COSV56231737; called by muse, mutect2, varscan2
- CELSR3 | c.7018del p.A2340Pfs*45 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | catalogued as COSV50904380; called by pindel, varscan2
- DRD1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769184130, COSV67104339; called by muse, mutect2, varscan2
- OTX2 | c.397C>T p.P133S (on ENST00000408990 / NM_172337.3; = p.P141S on NM_021728.4) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as CM051595; called by muse, mutect2, varscan2
- PCDHA4 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV63540150; called by muse, mutect2, varscan2
- PCDHA9 | c.1979C>G p.T660R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.088); catalogued as rs782628181, COSV65329248; called by muse, mutect2, varscan2
- PDE3B | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs766103990; called by muse, mutect2, varscan2
- PLA2G4C | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs759084365, COSV100843848; called by mutect2, varscan2
- SCARA5 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755412172, COSV57276767; called by muse, mutect2, varscan2
- ABCA13 | c.5248C>T p.L1750F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- BRWD3 | c.4007G>C p.G1336A | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIAPH3 | c.2614G>T p.D872Y (on ENST00000400324 / NM_001042517.2; = p.D609Y on NM_030932.3) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK2 | c.5470G>A p.D1824N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENO3 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2
- GPS2 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GPS2 | c.720G>C p.Q240H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- GRIK2 | c.723+1G>T p.X241_splice | Splice Site (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- MYO1C | c.698G>T p.G233V (on ENST00000648651 / NM_001080779.2; = p.G198V on NM_033375.5) | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NDRG3 | c.236A>G p.D79G (on ENST00000349004 / NM_032013.4; = p.D67G on NM_022477.4) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NIPBL | c.446A>C p.H149P | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- OGDHL | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2A12 | c.658A>T p.I220F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PKHD1L1 | c.2417C>A p.T806K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SH3PXD2A | c.168T>A p.D56E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- SNX21 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TRAV27 | c.31T>C p.W11R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRHR | c.960C>A p.Y320* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- WEE2 | c.1580C>T p.T527I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDHHC21 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, varscan2
- ZNF100 | c.386A>T p.E129V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ATP9A | c.1029C>T p.I343= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1329218217, COSV58763261; called by muse, mutect2, varscan2
- BMP2 | c.1080C>T p.C360= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- PPP1R1A | c.207G>A p.R69= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ZNF45 | c.1995T>C p.D665= | Silent (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
